Surgical pathology report (de-identified scan), TCGA case TCGA-24-1924, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1924-01A (Primary Tumor).

[page 1 of 6]
TCGA-24-1924

SURGICAL PATHOLOGY REPORT

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- ACUTE AND CHRONIC CERVICITIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- INACTIVE ENDOMETRIUM
- BENIGN POLYPS

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC SEROUS ADENOCARCINOMA IS IDENTIFIED IN LYMPHOVASCULAR SPACES
- ADENOMYOSIS
- LEIOMYOMAS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC SEROUS ADENOCARCINOMA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC SEROUS ADENOCARCINOMA ON SEROSAL SURFACE

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OMENTUM, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, SIGMOID NODULE, EXCISION

[page 2 of 6]
[REDACTED]

[REDACTED]

- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, LEFT PARAMETRIUM, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, RIGHT PELVIC SIDEWALL, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, RIGHT PARAMETRIUM, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

BLADDER, PERITONEUM, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

APPENDIX, EXCISION

- METASTATIC SEROUS ADENOCARCINOMA IN THE PERIAPPENDICEAL FAT

SOFT TISSUE, MORRISON'S POUCH, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, SPLENIC NODULE, EXCISION
- METASTATIC SEROUS ADENOCARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my
personal
examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED]
***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pickup 'uterus, cervix and left adnexa,' consisting of a hysterectomy specimen with left adnexa, weighing 92 grams. The uterus measures 4.5 x 4.5 x 0.5 cm and cervix measures 5 x 3 x 2.5 cm. Opened to show a 0.9 x 0.8 cm slightly raised area present on posterior aspect of endometrium. Showed surgeon. All for permanent," [REDACTED]

"Called to O.R. to pickup 'right adnexa,' consisting of an adnexa, weighing 26.4 grams, measuring 4.8 x 2.5 x 2.2 cm. There is a fallopian tube attached, measuring 5.2 x 0.4 x 0.4 cm. Inked black. Sectioned to show a glistening, grey, white, well-circumscribed, lobulated nodule, measuring 2.5 x 2.3 cm, that is within 0.1 cm from the ink. A portion of tumor is frozen. Rest for permanents," [REDACTED]

FS1: Adnexa, "R," resection
- "Adenocarcinoma," [REDACTED]

[REDACTED]

Microscopic Description and Comment:

Histologic sections show serous adenocarcinoma involving both left and right ovaries (synchronous primary tumors). Architecturally, the tumor has a well-developed papillary morphology in some areas; however, in other areas it is poorly differentiated and grows as broad sheets of cells that have a high cytologic grade. The tumor directly extends into the peri-adnexal soft tissue, and metastatic deposits of adenocarcinoma are present on the surface of the left fallopian tube and on the serosal surface of the uterus. In addition, we note lymphovascular tumor emboli within the myometrium of the uterus.

[page 3 of 6]
[REDACTED]

Metastatic serous adenocarcinoma is present in the tissue from the sigmoid nodule, appendix, spleen, right and left parametrium, right pelvic sidewall, [REDACTED] pouch, and bladder peritoneum.

Metastatic adenocarcinoma diffusely invades the omentum. [REDACTED]

[REDACTED]

History:

The patient is [REDACTED] with omental caking, peritoneal disease, ascites, and lesion of left adnexa. Operative procedure: Examination under anesthesia, exploratory laparotomy, omentectomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, tumor debulking, appendectomy.

Specimen(s) Received:

A: UTERUS, CERVIX, LEFT ADNEXA
B: RIGHT ADNEXA
C: OMENTUM
D: SIGMOID NODULE
E: LEFT PARAMETRIUM
F: RIGHT PELVIC SIDEWALL
G: RIGHT PARAMETRIUM
H: BLADDER PERITONEUM
I: APPENDIX
J: MORRISON'S POUCH
K: SPLENIC NODULE

Gross Description

The specimens are received in eleven containers of formalin, each labeled with the patient's name. The first container is labeled "uterus, cervix, left adnexa." It contains a uterus with attached left adnexa, with measurements and description matching the intraoperative consultation. The external os is oval-shaped, measuring 0.2 x <0.1 cm. The cervical epithelium is white with focal area of hemorrhage and unremarkable. The uterus has been previously bivalved to show an endocervical canal with mucoid papillary projections, measuring 3.2 cm in length with no gross lesions identified. The endometrial cavity measures 2.2 x 2.5 cm, and the lesion described intraoperatively is consistent with a polyp. The thickness of the endometrium is <0.1 cm and the myometrium thickness is from 1.3 to 1.6 cm. There are several subserosal nodules present in the posterior serosa, measuring from 0.2 to 0.5 cm in greatest dimension. Further sectioned to show a well circumscribed, white-tan, whorled nodule in the anterior wall of the myometrium, measuring 0.5 x 0.5 x 0.5 cm, consistent with a leiomyoma. The left fallopian tube measures 6 cm in length and 0.6 cm in maximum diameter. The serosal surface is tan and glistening. The left ovary measures 3 x 1.5 x 0.5 cm, and there are adhesions present on the serosal surface. In addition, two white, slightly firm, papillary foci are present in the mesovarian, each measuring 2 x 1 x 0.3 cm. Sections of the ovary are unremarkable. Labeled A1 - anterior cervix; A2 - posterior cervix; A3 - anterior endomyometrium; A4 - posterior endomyometrium; A5 to A7 - sections including the whole polypoid lesion on the posterior endometrium; A8 - sections of the intramural leiomyoma from the anterior wall; A9 - sections of the posterior myometrium including one of the subserosal nodules; A10 to A12 - the entire left ovary; A13 - left fallopian tube; A14 - right firm area in the mesovarian, the larger fragment is more distal. Jar 2.

The second container is labeled "R. adnexa, FS1/X1." It contains a white cassette labeled "FS" that contains a fragment of firm, white-tan tissue with a capsule, measuring 2 x 1.5 x 0.2 cm, consistent with the frozen section remnant. Labeled B1 (FS1). Also within the container is a fragment of previously inked and bivalved ovary and attached fallopian tube, with measurements and description matching the intraoperative consultation. The entire ovary

[page 4 of 6]
[REDACTED]

is replaced by white, firm, lobulated mass and no normal appearing ovary is identified. The fallopian tube measures 4.5 cm in length and 0.6 cm in maximum diameter. The serosal surface is glistening. Sections of the fallopian tube are unremarkable. Labeled B2 to B5 - random section of the tumor; B6 - random section of the fallopian tube. [REDACTED]

The third container is labeled "omentum." It contains a fragment of omentum with thickening, measuring 40 x 7 x 3.5 cm. There is a white, firm mass involving the whole fragment of omentum. Serial sections of the omentum show firm, white-yellow cut surface, consistent with tumor involvement. [REDACTED]

The fourth container is labeled "sigmoid nodule." It contains a previously opened tan-yellow nodule, measuring 3.5 x 2.5 x 2.5 cm. The external surface is smooth. There are areas of tan-yellow fibroadipose tissue in the inside of the nodule, and the nodule has a configuration of a cyst. The cyst wall has a thickness of <0.1 cm. Serial sections of the fibroadipose tissue show a thick-walled cyst with tan clay-like necrotic material inside the cyst, measuring 1 x 1 x 0.6 cm. No other lesions are identified. Labeled D1 - section of the cyst wall with the inner fibroadipose tissue. [REDACTED]

The fifth container is labeled "L. parametrium." It contains two fragments of brown-yellow fibroadipose tissue, measuring 4 x 1 x 0.4 cm and 6 x 2 x 0.5 cm. One firm nodule, measuring 1.2 x 0.5 x 0.5 cm is identified, consistent with tumor involvement. Labeled E1 - section of the nodule. [REDACTED]

The sixth container is labeled "R. pelvic sidewall." It contains a fragment of brown-tan fibroadipose tissue, measuring 2 x 1.8 x 0.4 cm. Sections of the fragment show slightly firm cut surface. [REDACTED]

The seventh container is labeled "R. parametrium." It contains two fragments of brown-tan fibroadipose tissue, measuring 4.5 x 2.5 x 1 cm and 10 x 1 x 0.4 cm. A multilocular nodule, measuring 2 x 2 x 1 cm is present in the small fragment. Sections of the nodule show a multilocular cyst with papillary, white projections inside the cyst. Sections of the larger fragment also show white, firm cut surface, consistent with tumor involvement. Labeled G1 - sections of the nodule from the smaller fragment; G2 - sections of the larger fragment. [REDACTED]

The eighth container is labeled "bladder peritoneum." It contains three fragments of white-tan fibroadipose tissue, measuring 2 x 1.6 x 0.4 cm and 7 x 3 x 0.6 cm. There are white, firm nodules in the two larger fragments, consistent with tumor involvement. Sections of the fragment show white, firm cut surface [REDACTED]

The ninth container is labeled "appendix." It contains an appendix with mesoappendix, measuring 6 cm in length and 0.7 cm in diameter (for the appendix) and 6 x 2 x 0.6 cm for the mesoappendix. There is also a loosely attached yellow-white tissue to the mesoappendix, measuring 4 x 1.5 x 0.6 cm. There are multiple white nodules in the mesoappendix, as well as the loosely attached fragments, consistent with tumor involvement. Sections of the loose fragments show white, firm material covering the fat. Labeled I1 - sections of the appendix; I2 - sections of appendix with mesoappendix, including the white, firm area and sections of the other loose fragments with white, firm area covering fat. Jar 1.

The tenth container is labeled "Morrison's pouch." It contains three fragments of white-yellow fibroadipose tissue, measuring 1.5 x 0.6 x 0.2 cm to 2 x 1.5 x 0.6 cm. Multiple white nodules are present within each fragment, and sections of these nodules show white, firm cut surface, consistent with tumor involvement. [REDACTED]

[page 5 of 6]
The eleventh container is labeled "splenic nodule." It contains two fragments of white-yellow fibroadipose tissue, measuring 3 x 0.5 x 0.5 cm and 5 x 2 x 1 cm. Serial sections of the fragments show white, firm cut surfaces, consistent with tumor involvement. Labeled K1.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION OF THE PRIMARY TUMOR(S) is:
Right and left ovary (synchronous primary tumors)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface bilaterally.
7. Tumor DOES invade the mesovarium.
8. Tumor IS PRESENT on the surface of the adjacent fallopian tube(s).
9. Tumor IS PRESENT on the surface of pelvic soft tissues (bladder, appendix, and sigmoid).
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: > 2 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
- 17 and 18. The total number of regional lymph nodes examined is: zero (0)
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	
T3c	IIIC	Macroscopic peritoneal	
metastasis beyond true pelvis		measuring > 2cm in greatest dimension	

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

[page 6 of 6]
[REDACTED]

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:
AJCC/UICC/FIGO Stage IIIC (T3c/NX/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 9252ef54-e5cd-4ac5-8af3-2a835aa1c518 (TCGA-24-1924.4199B57A-81F5-4D5F-9F4C-1E514DCD26DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).